FM case AD15536 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/e9aa17df-3a95-44eb-83c2-b2051edf35a9

Male, 53.5 years: Adenoid cystic carcinoma (ICD-O-3 8200/3); specimen biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 73% (pathologist estimate recorded by GDC). Sample type: Tumor.
